Gene-level copy-number profile of tumor specimen C3N-04382-02 from CPTAC case C3N-04382, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 47.9 years (17,484 days).
Specimen C3N-04382-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 86c1844f-b6bb-4275-ac3f-b5009231a05e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04382-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/688bcb8e-0aac-4362-bb8f-2793dafeab12

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 18,831; copy number 2: 26,437; copy number 3: 11,481; copy number 4: 1,467; copy number 5: 110; copy number 6: 14; copy number 8: 35; copy number 9: 7; copy number 10: 4.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–1): AC104164.2, MIR548BB.
- chr21:44,107,373–44,210,114, 2 genes (within-gene range 0–2): PWP2, GATD3A.
- chr22:35,606,764–35,729,483, 6 genes: MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5.
- chr22:36,281,280–36,387,967, 3 genes (within-gene range 0–2): MYH9, MIR6819, Z82215.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 170 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,745,249–143,760,669, 1 gene, copy number 5: AC239800.1.
- chr1:143,811,359–143,846,504, 2 genes, copy number 5–10: AC239798.1, AC239798.2.
- chr1:248,936,581–248,937,043, 1 gene, copy number 9: RPL23AP25.
- chr3:26,614,261–27,931,579, 19 genes, copy number 5: AC099754.1, LRRC3B, NEK10, MICOS10P3, RNU6-342P, AC099535.2, SLC4A7, RPS20P15, AC099535.1, RNU1-96P, AC137675.1, Y_RNA, AC098614.1, AC098614.2, KIAA1143P2, LINC02084, EOMES, LINC01980, LINC01981.
- chr3:32,105,689–32,168,709, 2 genes, copy number 5: GPD1L, AC094019.2.
- chr9:64,369,394–64,413,142, 2 genes, copy number 6: ANKRD20A4P, RNU6-1193P.
- chr9:64,462,819–64,466,498, 2 genes, copy number 6: CR769776.2, CYP4F25P.
- chr9:64,621,560–64,765,535, 5 genes, copy number 5: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr9:64,817,870–64,836,341, 1 gene, copy number 5: AL359955.1.
- chr9:65,189,995–65,230,861, 3 genes, copy number 10: BMS1P12, AL512605.1, AL512605.2.
- chr19:42,397,128–42,652,355, 1 gene, copy number 5 (within-gene range 1–5): LIPE-AS1.
- chr19:42,428,278–42,442,946, 1 gene, copy number 5 (within-gene range 1–5): CXCL17.
- chr19:42,507,304–44,993,341, 120 genes, copy number 5–9 (broad region; genes not listed).
- chr19:53,431,984–53,608,451, 10 genes, copy number 6: TPM3P9, ZNF761, AC022137.3, ZNF813, TPM3P6, AC022137.1, AC011487.1, AC011487.3, ZNF331, AC011487.2.

Autosomal genes at a single copy (total copy number 1): 17,663. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
